Surgical pathology report (de-identified scan), TCGA case TCGA-Q1-A5R3, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Oklahoma HSC, specimen TCGA-Q1-A5R3-01A (Primary Tumor).

MEDICAL CENTER
LABORATORY

PAGE:1

Specimen Inquiry

PATIENT:

ACCT #:

LOC:

U#:

REG DR:

SPEC #:

CLINICAL HISTORY:

STAT CALL DR. WITH RESULTS ASAP* CERVICAL CANCER (ICD 180.9), ABN UTERINE BLEEDING (ICD 626.9); PT HAS SEVERE CERVICAL ATYPICAL CELLS

SPECIMEN/PROCEDURE:

1. ENDOCERVIX/ECC

IMPRESSION:

ENDOCERVICAL CURETTINGS:

Fragments of squamous cell carcinoma, large cell nonkeratinizing, grade II with focal stromal invasion.

GROSS DESCRIPTION:

1. Received in formalin labeled with the patient's name and ECC. Received is a 1 x 0.5 x 0.2 cm aggregate of pale pink to pale tan irregular tissue fragments admixed with red-brown blood clot. The specimen is entirely submitted in cassette 1A.

COPIES TO:

No Primary or Family Physician

ICD 180.9
path Carcinoma, large cell-squamous cell,
non-keratinizing NOS 8672/3
CSCF Carcinoma, squamous cell NOS 8070/3
Site: Cervix NOS C53.9
JAD 4/12/13

CPT Codes:

ENDOCERVICAL 88305

ICD9 Codes:

180.9

I have personally reviewed the material
(specimen/slide) and approve this final report.

** END OF REPORT **

Source: NCI Genomic Data Commons file bfbdd570-b54b-43a9-b5b5-0823a60125d7 (TCGA-Q1-A5R3.1E8B41FC-2317-4EEA-BDD8-40BC40D36BA6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).